Somatic mutation profile of tumor specimen MP2PRT-PATBMU-TMP1-A (aliquot MP2PRT-PATBMU-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATBMU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,297 days).
Specimen MP2PRT-PATBMU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ddae687-cc35-499d-bb38-6abb320237fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBMU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBMU-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dbcd1fc-0874-438e-8328-88b3fd432a96

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEND6 | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 62/148 reads (42%) | catalogued as COSV66070576; called by muse, mutect2, varscan2
- ERO1B | c.675C>T p.G225= | Splice Region (SNP) | VAF 65/152 reads (43%) | catalogued as rs757548395, COSV59242152; called by muse, mutect2, varscan2
- FBP2 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs374397427; called by muse, mutect2, varscan2
- HOXA1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 116/283 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as COSV58030611; called by muse, mutect2, varscan2
- HPS6 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 81/619 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.368); catalogued as rs1450101908, COSV54626308; called by muse, mutect2, varscan2
- NUDC | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as rs1462394884; called by muse, mutect2, varscan2
- PCMT1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374534669; called by muse, mutect2, varscan2
- POM121L12 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); catalogued as rs565383229, COSV68693234; called by muse, mutect2
- PXDN | c.3410C>T p.T1137M | Missense Mutation (SNP) | VAF 56/645 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.206); catalogued as rs750668748, COSV53244813; called by muse, mutect2
- RGS12 | c.3977C>T p.A1326V | Missense Mutation (SNP) | VAF 18/565 reads (3%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV58755994; called by muse, mutect2
- SLIT3 | c.739C>A p.H247N | Missense Mutation (SNP) | VAF 144/302 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as COSV60601321; called by muse, varscan2
- AC092835.1 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO3 | c.1543C>G p.P515A | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ASTN1 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 167/411 reads (41%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CACNA1B | c.4146G>C p.Q1382H | Missense Mutation (SNP) | VAF 153/324 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- KAT2B | c.215C>G p.S72W | Missense Mutation (SNP) | VAF 58/583 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 110/120 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEE2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2
- PDK4 | c.312G>C p.E104D | Missense Mutation (SNP) | VAF 118/252 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RNF213 | c.7358G>A p.G2453E | Missense Mutation (SNP) | VAF 155/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF213 | c.8075G>C p.C2692S | Missense Mutation (SNP) | VAF 183/369 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC13A4 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC35G5 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 195/389 reads (50%) | SIFT tolerated (0.95); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- THNSL1 | c.2132G>C p.R711T | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WASHC2A | c.941C>G p.S314* | Nonsense Mutation (SNP) | VAF 38/172 reads (22%) | called by muse, mutect2, varscan2
- ZFP36 | c.191C>T p.S64F (on ENST00000594442; = p.S58F on NM_003407.5) | Missense Mutation (SNP) | VAF 18/600 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ZNF433 | c.1088A>G p.E363G | Missense Mutation (SNP) | VAF 147/309 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- ZNF735 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HFE | c.957C>T p.I319= | Silent (SNP) | VAF 135/260 reads (52%) | catalogued as COSV58513235; called by muse, mutect2, varscan2
- NPAS3 | c.1473G>A p.E491= (on ENST00000356141 / NM_001164749.2; = p.E459= on NM_022123.3) | Silent (SNP) | VAF 152/351 reads (43%) | catalogued as rs897609972; called by muse, mutect2, varscan2
- PRKG2 | c.1989C>G p.L663= | Silent (SNP) | VAF 9/207 reads (4%) | catalogued as rs934995848, COSV52321732; called by muse, mutect2
- RNF213 | c.6438G>A p.L2146= | Silent (SNP) | VAF 114/253 reads (45%) | catalogued as rs750346938, COSV60394218; called by muse, mutect2, varscan2
- SCN2A | c.4605C>T p.I1535= | Silent (SNP) | VAF 11/286 reads (4%) | called by muse, mutect2
- TOP2A | c.3474A>G p.L1158= | Silent (SNP) | VAF 76/181 reads (42%) | catalogued as rs1308398377; called by muse, mutect2, varscan2
- MRO | c.-33C>G | 5'UTR (SNP) | VAF 116/263 reads (44%) | called by muse, mutect2, varscan2
